Surgical pathology report (de-identified scan), TCGA case TCGA-M7-A725, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of North Carolina, specimen TCGA-M7-A725-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

C94 ICD-O-3
Adenocarcinoma, acinar 8140/3
path
Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9
9/8/12/13

Diagnosis:

A: Lymph nodes, right pelvic, dissection

- No tumor identified in four lymph nodes (0/4)

B: Lymph nodes, left pelvic, dissection

- No tumor identified in seven lymph nodes (0/7)

C: Prostate, radical prostatectomy

Tumor histologic type: prostatic adenocarcinoma, acinar

Tumor grade (Gleason system): 7 (4+3) with tertiary Gleason pattern 5 (5% of tumor volume)

Approximate percentage of prostate involved by tumor: overall 40%; right 15%, left 65%

Extent of tumor:

Location of tumor involvement in prostate: bilateral involvement from apex to near base

Confinement/non-confinement of tumor within the prostatic capsule: non-confinement of tumor

Location of extracapsular tumor involvement: left mid (C15, C17)

Type of extracapsular tissue involved within tumor: adipose tissue

Lymphovascular space invasion: present

Seminal vesicles (invasion of muscular wall required): right extraprostatic seminal vesicle involved by tumor (C11), left seminal vesicle negative for tumor

Histologic assessment of surgical margins: positive soft tissue margins in left mid linear extent <1 mm in each focus, involving non-contiguous sections (C16, C18)

Other significant findings: high grade prostatic intraepithelial neoplasia, extensive perineural involvement

Lymph nodes: no tumor identified in 11 lymph nodes (0/11)

Size and location of largest tumor metastasis: not applicable

[page 2 of 3]
Extracapsular extension of tumor in lymph nodes: not applicable

AJCC Staging:

pT3b

pN0

This staging information is based on this pathologic specimen and may be incomplete. A comprehensive review of all available information is recommended to determine final staging.

Clinical History:

-year-old male with prostate cancer.

Gross Description:

Received are three appropriately labeled containers.

Container A is additionally labeled "right pelvic lymph nodes." It holds fragments of yellow/tan fibroadipose tissue that in aggregate measure 5.5 x 5.5 x 1.0 cm. Multiple candidate lymph nodes are palpated, with the largest measuring 3.1 x 1.4 x 0.9 cm. The candidate lymph nodes are submitted per block summary. Adipose tissue remains in formalin.

Block Summary:

A1 - one candidate lymph node, sectioned
A2-A3 - one candidate lymph node, sectioned
A4-A5 - largest candidate lymph node, sectioned
A6-A9 - multiple candidate lymph nodes

Container B is additionally labeled "left pelvic lymph nodes." It holds multiple fragments of yellow/tan fibroadipose tissue that in aggregate measure 5.0 x 4.5 x 0.9 cm.

Block summary:

B1-B3 - largest candidate lymph node, sectioned
B4 - one candidate lymph node, sectioned
B5 - multiple candidate lymph nodes
B6 - multiple candidate lymph nodes

[page 3 of 3]
Container C:

Specimen fixation: formalin

Type of specimen(s) received: robot assisted laparoscopic

Size of specimen: 4.4 cm medial to lateral, 4.4 cm superior to inferior, 3.6 cm anterior to posterior

Weight of specimen: 40.0 grams

Orientation: Inking: right=blue, left=black, apex=yellow, base/bladder neck=red

Size and description of other organs or structures: The prostate is received with bilateral seminal vesicles and vas deferents intact.

Gross description of prostate: Prostatic tissue demonstrates grossly evidence of mild prostatic hyperplasia by examination. No gross carcinoma or areas of necrosis or hemorrhage are identified.

Digital photograph taken: not taken

Block summary:

C1 - right apex, perpendicular sections
C2-C10 - right prostate, apex to base, respectively, entire posterior lobe
C11 - right seminal vesicle tissue and right vas deferens margin, en face
C12 - right bladder neck margin, perpendicular sections
C13 - left apex, perpendicular sections
C14-C22 left prostate, apex to base, respectively, entire posterior lobe
C23 - left seminal vesicle tissue and left vas deferens margin, en face
C24 - left bladder neck margin, perpendicular sections

Source: NCI Genomic Data Commons file 32e3ad65-495a-4917-8c53-182fbea2bc39 (TCGA-M7-A725.5885079D-F3C7-44DB-9BA1-60DCA1C9919C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).